Somatic mutation profile of tumor specimen MMRF_1223_3_BM_CD138pos (aliquot MMRF_1223_3_BM_CD138pos_T1_KHS5U_L08698) from MMRF case MMRF_1223, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 35.7 years (13,027 days).
Specimen MMRF_1223_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77741fc9-3582-4969-8508-f890628ca089.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1223_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1223_2_PB_Whole_C3_KBS5U_L05821; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd7fa522-6791-4c36-9144-c4eaf01236ad

The open-access MAF lists 43 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, 3'UTR 10, Silent 4, Intron 3, Splice Region 2, 3'Flank 2, 5'UTR 2, Nonsense Mutation 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C10orf71 | c.3806C>T p.A1269V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs924510693, COSV60507375; called by muse, mutect2, varscan2
- CCDC114 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759075558; called by muse, mutect2, varscan2
- CR1 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs571542796; called by muse, mutect2, varscan2
- GAS2L2 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs782029559; called by muse, mutect2, varscan2
- GRAMD1A | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs201696171, COSV58765928; called by muse, mutect2, varscan2
- IGKV1-5 | c.57T>C p.G19= | Splice Region (SNP) | VAF 40/66 reads (61%) | catalogued as rs530103870; called by muse, mutect2, varscan2
- IGKV1-8 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 46/73 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs376991397; called by muse, mutect2, varscan2
- KCNJ5 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs142140011; called by muse, mutect2, varscan2
- MYH14 | c.4315C>T p.R1439C | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs867601827, COSV51809446; called by muse, mutect2, varscan2
- PRPF8 | c.4498G>A p.G1500R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59268806; called by muse, mutect2, varscan2
- SYNE1 | c.3850C>T p.R1284W (on ENST00000367255 / NM_182961.4; = p.R1291W on NM_033071.3) | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs140780725; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TNC | c.4945A>G p.N1649D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV60790705; called by muse, mutect2, varscan2
- ADK | c.220A>T p.K74* (on ENST00000286621; = p.K57* on NM_001123.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.603+7G>T | Splice Region (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.1640C>A p.T547N (on ENST00000450689 / NM_001142749.3; = p.T380N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- IGKV1-5 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 15/21 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IL20RA | c.1334C>G p.T445R | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KCTD3 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MEPE | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 96/266 reads (36%) | called by muse, mutect2, varscan2
- RASGRF2 | c.2615C>G p.A872G | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2
- UGT3A2 | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RECQL4 | c.2208C>T p.A736= | Silent (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
- SEC31A | c.2266T>C p.L756= (on ENST00000355196 / NM_001318120.1; = p.L717= on NM_016211.4) | Silent (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- SNED1 | c.1125C>T p.C375= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as rs1173949099, COSV60023639; called by muse, mutect2
- SORBS2 | c.1170C>T p.D390= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs1232046457; called by muse, mutect2, varscan2
- C18orf54 | c.*1046G>T | 3'UTR (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- CPZ | c.*47C>T | 3'UTR (SNP) | VAF 9/21 reads (43%) | catalogued as rs751996171; called by muse, mutect2, varscan2
- DIPK2A | c.657+250T>C | Intron (SNP) | VAF 88/263 reads (33%) | called by muse, mutect2, varscan2
- DLC1 | c.1348+90629G>A | Intron (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- FAM76B | c.*2037T>A | 3'UTR (SNP) | VAF 16/65 reads (25%) | catalogued as rs1313908741; called by muse, mutect2, varscan2
- FHAD1 | c.4122+5879C>T | Intron (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2
- GRID1 | c.*1840G>T | 3'UTR (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- HPS3 | c.-14C>T | 5'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs1189093183; called by muse, mutect2, varscan2
- LARS2 | chr3:45549481 A>G | 3'Flank (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- MAGIX | chrX:49167496 C>A | 3'Flank (SNP) | VAF 40/67 reads (60%) | catalogued as COSV100890549; called by muse, mutect2, varscan2
- MAT1A | c.*387G>A | 3'UTR (SNP) | VAF 6/62 reads (10%) | catalogued as rs969778829; called by muse, mutect2, varscan2
- MOB1B | c.*6052A>T | 3'UTR (SNP) | VAF 8/74 reads (11%) | catalogued as rs1254930189; called by muse, mutect2
- PTCHD1 | c.*7323C>T | 3'UTR (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- RNF115 | c.*980A>T | 3'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- SGO1 | c.*206C>T | 3'UTR (SNP) | VAF 24/69 reads (35%) | catalogued as rs753900344; called by muse, mutect2, varscan2
- SORL1 | c.*4061dup | 3'UTR (INS) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- THUMPD1 | c.-168C>A | 5'UTR (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
